Somatic mutation profile of tumor specimen MMRF_2229_1_BM_CD138pos (aliquot MMRF_2229_1_BM_CD138pos_T1_KHS5U_L11042) from MMRF case MMRF_2229, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.8 years (25,863 days).
Specimen MMRF_2229_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3477420f-5ec2-472e-9bbc-b08316ff4d22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2229_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2229_1_PB_WBC_C2_KHS5U_L11041; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f96e620c-d465-4889-91e6-a20ecee1de1e

The open-access MAF lists 155 somatic variants for this specimen: 63 protein-altering or splice-affecting, 18 silent, 74 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, 3'UTR 31, Intron 24, Silent 18, 3'Flank 6, RNA 6, Frame Shift Del 4, 5'UTR 4, Nonsense Mutation 4, 5'Flank 3, Splice Region 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 18/79 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913482, CM950469, COSV53390662; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FGFR3 | c.*1475T>C | 3'UTR (SNP) | VAF 14/93 reads (15%) | catalogued as rs121913101, CM950478, CM950479; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARHGAP31 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV51798783; called by muse, mutect2, varscan2
- CDCP1 | c.1556C>A p.T519N | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs761817189; called by muse, mutect2, varscan2
- DHRS12 | c.109C>T p.Q37* (on ENST00000444610 / NM_001377930.1; = p.S15= on NM_024705.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 54/96 reads (56%) | catalogued as rs930957541; called by muse, mutect2, varscan2
- IGHV2-70 | c.145A>T p.S49C | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as rs374002647; called by muse, varscan2
- IGHV4-39 | c.8T>C p.L3P | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as rs748383271; called by muse, varscan2
- IGKJ3 | c.3A>T p.*1= | Missense Mutation (SNP) | VAF 80/182 reads (44%) | catalogued as rs369861497; called by muse, varscan2
- IGLV3-1 | c.152C>A p.A51D | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as rs138666033; called by muse, varscan2
- IGLV3-1 | c.226A>G p.I76V | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.445); catalogued as rs374050608; called by muse, varscan2
- IGLV3-1 | c.268A>T p.T90S | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); catalogued as rs367981147; called by muse, varscan2
- KIF26B | c.3982del p.V1328Cfs*38 | Frame Shift Del (DEL) | VAF 31/97 reads (32%) | catalogued as rs778507313; called by mutect2, pindel, varscan2
- KIT | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 101/241 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs147943899, COSV55400979; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KSR1 | c.2068C>T p.Q690* (on ENST00000644974 / NM_001367810.1; = p.Q575* on NM_014238.2) | Nonsense Mutation (SNP) | VAF 32/337 reads (9%) | catalogued as rs774669318; called by muse, mutect2
- NLRP5 | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 149/528 reads (28%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs759300867, COSV66762557; called by muse, mutect2, varscan2
- RFFL | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1393506806; called by muse, varscan2
- RFFL | c.508G>T p.V170F | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as rs1259805224; called by muse, mutect2, varscan2
- SCTR | c.671A>G p.Y224C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99191764; called by muse, mutect2, varscan2
- SFSWAP | c.2345C>T p.S782F | Missense Mutation (SNP) | VAF 40/293 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); catalogued as COSV99906142; called by muse, mutect2, varscan2
- SMOX | c.1131G>C p.W377C | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1400576613; called by muse, mutect2, varscan2
- SPACA6 | c.731-5C>A | Splice Region (SNP) | VAF 42/145 reads (29%) | catalogued as rs1382148999; called by muse, mutect2, varscan2
- SZT2 | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.883); catalogued as rs759765444; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THNSL1 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1228383061; called by muse, mutect2, varscan2
- TNFRSF11B | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375274060; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPK1 | c.215_216del p.F72* | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs1322900965; called by mutect2, pindel, varscan2
- TTN | c.71147G>A p.R23716H (on ENST00000591111; = p.R16292H on NM_003319.4) | Missense Mutation (SNP) | VAF 90/280 reads (32%) | PolyPhen benign (0.006); catalogued as rs397517703; ClinVar: uncertain significance; called by muse, varscan2
- ZNF37A | c.1276C>T p.L426F | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV100697312; called by muse, mutect2, varscan2
- ZNF74 | c.1402G>A p.G468S | Missense Mutation (SNP) | VAF 112/224 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1035045395, COSV62624166; called by muse, mutect2, varscan2
- ACTR10 | c.1100T>C p.I367T | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.696); called by muse, mutect2
- ADORA2B | c.800A>G p.K267R | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARHGAP29 | c.2538T>G p.F846L | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ARHGDIB | c.522_524del p.N174del | In Frame Del (DEL) | VAF 40/118 reads (34%) | called by pindel, varscan2
- ATP5PB | c.693+2T>G p.X231_splice | Splice Site (SNP) | VAF 71/179 reads (40%) | called by muse, mutect2, varscan2
- ATP8B3 | c.2086T>A p.C696S | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCL10 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 76/201 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- C11orf80 | c.494A>C p.E165A | Missense Mutation (SNP) | VAF 88/287 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- C3 | c.2980G>A p.A994T | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- CCT8 | c.776T>C p.I259T | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CHST9 | c.1067T>C p.L356P | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAJC13 | c.4300G>A p.A1434T | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DOCK1 | c.5150C>A p.T1717N | Missense Mutation (SNP) | VAF 31/287 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- DUOX1 | c.4407C>T p.Y1469= | Splice Region (SNP) | VAF 18/342 reads (5%) | called by muse, mutect2
- HJURP | c.800T>C p.M267T | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KCND3 | c.1595G>A p.R532K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- KIAA1755 | c.1633T>C p.S545P | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- LHFPL3 | c.611T>C p.M204T | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2
- MIOS | c.2627A>T p.*876Lext*15 | Nonstop Mutation (SNP) | VAF 36/496 reads (7%) | called by muse, mutect2
- NEDD4 | c.1849G>T p.E617* (on ENST00000508342 / NM_001284338.1; = p.E198* on NM_006154.4) | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- NGEF | c.171C>G p.I57M | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PCDH9 | c.1776_1777del p.V593Nfs*12 | Frame Shift Del (DEL) | VAF 48/117 reads (41%) | called by mutect2, pindel, varscan2
- POLL | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.296); called by muse, varscan2
- POU2F2 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- RAB17 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.212); called by muse, mutect2
- RFFL | c.241G>C p.G81R | Missense Mutation (SNP) | VAF 130/296 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- SDCCAG8 | c.1455T>A p.D485E | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- SH2D3A | c.415C>G p.L139V | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- SPOCK2 | c.742_743del p.D248Lfs*14 | Frame Shift Del (DEL) | VAF 8/71 reads (11%) | called by mutect2, pindel
- SPPL2C | c.791G>T p.C264F | Missense Mutation (SNP) | VAF 92/231 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMOD3 | c.985A>C p.T329P | Missense Mutation (SNP) | VAF 35/388 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.623); called by muse, mutect2
- WNT8A | c.576G>T p.Q192H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZAN | c.6275G>A p.S2092N | Missense Mutation (SNP) | VAF 111/314 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZC3H11B | c.2179C>T p.L727F | Missense Mutation (SNP) | VAF 87/464 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF680 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- ZNF749 | c.1732C>G p.Q578E | Missense Mutation (SNP) | VAF 19/376 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- C6 | c.1327C>T p.L443= | Silent (SNP) | VAF 33/258 reads (13%) | called by muse, mutect2, varscan2
- CKAP4 | c.1629C>T p.V543= | Silent (SNP) | VAF 27/216 reads (13%) | catalogued as COSV65172258; called by muse, mutect2, varscan2
- GABRA4 | c.360C>T p.N120= | Silent (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- H2BC7 | c.372C>T p.S124= | Silent (SNP) | VAF 230/460 reads (50%) | catalogued as rs766252240; called by muse, mutect2, varscan2
- IGHV2-70 | c.201G>A p.E67= | Silent (SNP) | VAF 64/200 reads (32%) | catalogued as rs148856487; called by muse, varscan2
- KCNAB2 | c.963C>T p.L321= | Silent (SNP) | VAF 16/95 reads (17%) | called by muse, mutect2, varscan2
- LMTK3 | c.1560G>C p.T520= | Silent (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- MAP7D1 | c.1077G>A p.P359= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs746310011; called by muse, varscan2
- MMRN2 | c.1638C>T p.A546= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as rs750415609; called by muse, mutect2, varscan2
- MPDZ | c.354T>G p.A118= | Silent (SNP) | VAF 57/137 reads (42%) | catalogued as rs1291365629; called by muse, mutect2, varscan2
- POLL | c.21G>A p.L7= | Silent (SNP) | VAF 22/214 reads (10%) | called by muse, mutect2
- RRAS | c.480C>T p.F160= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as rs1353880358, COSV55868369; called by muse, mutect2, varscan2
- TBKBP1 | c.771G>T p.L257= | Silent (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- TERT | c.1515G>T p.L505= | Silent (SNP) | VAF 11/246 reads (4%) | called by muse, mutect2
- TMEM38A | c.105C>T p.L35= | Silent (SNP) | VAF 16/188 reads (9%) | catalogued as COSV99495535; called by muse, mutect2
- VHL | c.438T>A p.P146= | Silent (SNP) | VAF 14/405 reads (3%) | catalogued as COSV56553297; called by muse, mutect2
- ZMYND15 | c.207C>T p.I69= | Silent (SNP) | VAF 20/279 reads (7%) | catalogued as COSV99352002; called by muse, mutect2
- ZNF837 | c.726G>A p.A242= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as rs1281798158; called by muse, mutect2
- AC235097.1 | n.426A>G | RNA (SNP) | VAF 26/32 reads (81%) | called by muse, mutect2, varscan2
- ADGRF1 | c.611+743G>T | Intron (SNP) | VAF 67/232 reads (29%) | called by muse, mutect2, varscan2
- AFDN | chr6:167976179 G>T | 3'Flank (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- ANO3 | c.*165C>T | 3'UTR (SNP) | VAF 62/175 reads (35%) | called by muse, mutect2, varscan2
- ASB3 | c.*3+161A>G | Intron (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- ASTN1 | c.*2851A>G | 3'UTR (SNP) | VAF 36/109 reads (33%) | catalogued as rs1458079445; called by muse, mutect2, varscan2
- BCAS4 | chr20:50877186 C>A | 3'Flank (SNP) | VAF 29/92 reads (32%) | called by muse, mutect2, varscan2
- BCR | chr22:23180126 A>G | 5'Flank (SNP) | VAF 20/51 reads (39%) | catalogued as rs867197904; called by muse, mutect2, varscan2
- C16orf97 | n.282G>A | RNA (SNP) | VAF 20/172 reads (12%) | called by muse, mutect2, varscan2
- CACNA1A | c.1672-11C>T | Intron (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- CCDC149 | c.*1710C>T | 3'UTR (SNP) | VAF 23/44 reads (52%) | called by muse, mutect2, varscan2
- CDRT15P2 | n.179G>A | RNA (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- COPS9 | chr2:240136766 A>G | 5'Flank (SNP) | VAF 6/17 reads (35%) | catalogued as rs925909392; called by muse, mutect2, varscan2
- CSRP1 | c.411+21G>A | Intron (SNP) | VAF 45/230 reads (20%) | catalogued as rs1453523193; called by muse, mutect2, varscan2
- CXCL12 | c.*71C>T | 3'UTR (SNP) | VAF 113/299 reads (38%) | called by muse, mutect2, varscan2
- CYSLTR2 | c.*1380C>A | 3'UTR (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- DEPDC5 | c.1870+3625G>T | Intron (SNP) | VAF 11/143 reads (8%) | called by muse, mutect2
- DHCR7 | c.*171C>A | 3'UTR (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- DNAH3 | c.2366+43T>C | Intron (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2
- EPB41L4B | c.1409+3157C>A | Intron (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- EPHA7 | c.*1839T>A | 3'UTR (SNP) | VAF 10/54 reads (19%) | catalogued as COSV65180607; called by muse, mutect2, varscan2
- ERO1B | c.*1966G>C | 3'UTR (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2, varscan2
- ERO1B | c.*123T>G | 3'UTR (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2
- FGF12 | c.-40C>T | 5'UTR (SNP) | VAF 12/43 reads (28%) | catalogued as rs751922772; called by muse, mutect2, varscan2
- FOXK1 | c.*284C>T | 3'UTR (SNP) | VAF 48/125 reads (38%) | called by muse, mutect2, varscan2
- FUS | c.-73C>T | 5'UTR (SNP) | VAF 27/168 reads (16%) | catalogued as rs1351763361; called by muse, mutect2, varscan2
- FZD3 | c.*8089A>G | 3'UTR (SNP) | VAF 26/89 reads (29%) | called by muse, mutect2, varscan2
- GCSAM | chr3:112133265 T>G | 5'Flank (SNP) | VAF 77/162 reads (48%) | called by muse, mutect2, varscan2
- GFPT2 | c.341-62T>C | Intron (SNP) | VAF 47/410 reads (11%) | catalogued as rs1178507649; called by muse, mutect2, varscan2
- GLRX | c.-54_-43del | 5'UTR (DEL) | VAF 34/119 reads (29%) | called by mutect2, varscan2
- GPC1 | c.*470C>T | 3'UTR (SNP) | VAF 9/129 reads (7%) | called by muse, mutect2
- HMBS | c.651+54A>G | Intron (SNP) | VAF 12/71 reads (17%) | catalogued as rs755636016; called by muse, mutect2, varscan2
- HMX1 | c.*388G>A | 3'UTR (SNP) | VAF 24/120 reads (20%) | called by muse, mutect2, varscan2
- HNF4G | chr8:75566702 A>C | 3'Flank (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- HOXD3 | chr2:176173932 T>A | 3'Flank (SNP) | VAF 33/78 reads (42%) | called by muse, mutect2, varscan2
- IGKV4-1 | c.-114A>T | 5'UTR (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- IL36G | c.*421C>T | 3'UTR (SNP) | VAF 4/94 reads (4%) | called by muse, mutect2
- INPP5E | c.*685A>T | 3'UTR (SNP) | VAF 35/86 reads (41%) | called by muse, mutect2, varscan2
- IRF2BP2 | c.*1121G>A | 3'UTR (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- L3MBTL4 | c.1471+15820A>C | Intron (SNP) | VAF 55/162 reads (34%) | catalogued as rs1244232472; called by muse, mutect2, varscan2
- LINC00482 | n.1228G>C | RNA (SNP) | VAF 17/115 reads (15%) | called by muse, mutect2, varscan2
- MAP9 | c.1822-2148T>G | Intron (SNP) | VAF 41/95 reads (43%) | called by muse, mutect2
- MIR4262 | n.1G>A | RNA (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- MUC20 | chr3:195735180 T>A | 3'Flank (SNP) | VAF 37/149 reads (25%) | called by mutect2, varscan2
- MYLK | c.*3348A>G | 3'UTR (SNP) | VAF 50/101 reads (50%) | called by muse, mutect2, varscan2
- OTUD7B | c.*627T>C | 3'UTR (SNP) | VAF 6/106 reads (6%) | catalogued as rs1553770853; called by muse, mutect2
- PACRG | c.614-67741T>A | Intron (SNP) | VAF 69/247 reads (28%) | called by muse, mutect2, varscan2
- PHF21B | c.*1050C>T | 3'UTR (SNP) | VAF 34/255 reads (13%) | called by muse, mutect2, varscan2
- PIK3C3 | c.*6160A>T | 3'UTR (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- POLL | c.115+100G>A | Intron (SNP) | VAF 14/104 reads (13%) | called by muse, varscan2
- PSD3 | c.*7698C>T | 3'UTR (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- PSMC4 | c.842-31G>T | Intron (SNP) | VAF 160/297 reads (54%) | called by muse, mutect2, varscan2
- PSMD1 | c.1998+95C>T | Intron (SNP) | VAF 15/359 reads (4%) | called by muse, mutect2
- PTGER3 | c.1077+1809G>A | Intron (SNP) | VAF 25/106 reads (24%) | called by muse, mutect2, varscan2
- QRSL1 | c.849+23T>G | Intron (SNP) | VAF 26/227 reads (11%) | called by muse, mutect2, varscan2
- RGS8 | chr1:182646410 T>A | 3'Flank (SNP) | VAF 7/93 reads (8%) | called by muse, mutect2
- RNF152 | c.*514C>T | 3'UTR (SNP) | VAF 16/88 reads (18%) | catalogued as COSV100455278; called by muse, mutect2, varscan2
- RPS11 | c.223+129G>T | Intron (SNP) | VAF 57/219 reads (26%) | called by muse, mutect2, varscan2
- SDHAP1 | n.1268C>T | RNA (SNP) | VAF 20/330 reads (6%) | called by muse, mutect2
- SEC16B | c.1775+84T>A | Intron (SNP) | VAF 96/238 reads (40%) | catalogued as COSV57623667; called by mutect2, varscan2
- SEC16B | c.1775+82T>G | Intron (SNP) | VAF 94/235 reads (40%) | called by mutect2, varscan2
- SLC25A38 | c.*20G>A | 3'UTR (SNP) | VAF 11/53 reads (21%) | catalogued as rs566120398, COSV99827839; called by muse, mutect2, varscan2
- SLC48A1 | c.*2027del | 3'UTR (DEL) | VAF 29/88 reads (33%) | called by mutect2, pindel, varscan2
- SOX21 | c.*873A>G | 3'UTR (SNP) | VAF 36/62 reads (58%) | called by muse, mutect2, varscan2
- SRI | c.*193G>A | 3'UTR (SNP) | VAF 24/131 reads (18%) | called by muse, mutect2, varscan2
- TBC1D22A | c.*841T>C | 3'UTR (SNP) | VAF 58/160 reads (36%) | called by muse, mutect2, varscan2
- THADA | c.2312-2530A>G | Intron (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- TOP3A | c.240+73A>C | Intron (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- TTBK1 | c.*765G>A | 3'UTR (SNP) | VAF 20/214 reads (9%) | called by muse, mutect2
- TYW1 | c.375+59C>T | Intron (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- YME1L1 | c.*1159dup | 3'UTR (INS) | VAF 15/54 reads (28%) | catalogued as rs1050556730; called by mutect2, varscan2
- ZFAND1 | c.637-24T>A | Intron (SNP) | VAF 44/201 reads (22%) | called by muse, mutect2, varscan2
- ZNF474 | c.*33C>G | 3'UTR (SNP) | VAF 34/534 reads (6%) | called by muse, mutect2
